Somatic mutation profile of tumor specimen TCGA-KC-A4BN-01A (aliquot TCGA-KC-A4BN-01A-61D-A257-08) from TCGA case TCGA-KC-A4BN, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.8 years (20,392 days).
Specimen TCGA-KC-A4BN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8fe0c7cb-112d-40ee-8c1a-9bc716ace2ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KC-A4BN-10A (Blood Derived Normal), aliquot TCGA-KC-A4BN-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/820cfa11-17c9-411b-ac0a-242a3cdc54a3

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 10, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARRDC2 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs764482910, COSV104382086, COSV99716586; called by muse, mutect2, varscan2
- BAHD1 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.257); catalogued as rs778734004, COSV101346715; called by muse, mutect2, varscan2
- BICD1 | c.2078C>T p.A693V | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.138); catalogued as rs746325904, COSV55689057; called by muse, mutect2, varscan2
- LPA | c.2663C>T p.T888M | Missense Mutation (SNP) | VAF 51/249 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs546612209, COSV60298128; called by muse, mutect2, varscan2
- OR4Q3 | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV59178519; called by muse, mutect2, varscan2
- PDHX | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.173); catalogued as COSV99927227; called by muse, mutect2, varscan2
- RIMS2 | c.2196+2T>A p.X732_splice (on ENST00000666250 / NM_001348490.2; = p.X540_splice on NM_014677.5 and 7 other RefSeq transcripts) | Splice Site (SNP) | VAF 8/57 reads (14%) | catalogued as COSV99162408; called by muse, mutect2, varscan2
- RIPOR2 | c.1076T>G p.F359C | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99428595; called by muse, mutect2, varscan2
- SLC30A4 | c.1222A>G p.I408V | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1283464439, COSV99970130; called by muse, mutect2
- SMARCA1 | c.2938G>C p.D980H | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV100946359; called by muse, mutect2, varscan2
- ZNF430 | c.730T>C p.W244R | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.02); catalogued as COSV99841582; called by muse, mutect2, varscan2
- ESF1 | c.2394A>G p.E798= | Silent (SNP) | VAF 36/171 reads (21%) | catalogued as COSV99176273; called by muse, mutect2, varscan2
